Gene-level copy-number profile of tumor specimen TCGA-EO-A3KU-01A from TCGA case TCGA-EO-A3KU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 68.8 years (25,116 days).
Specimen TCGA-EO-A3KU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.b2c845f0-18ac-4b85-b0f9-43a12d2eebce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A3KU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6e4dd71-cdf3-4e4b-a55e-5a8ab5fbdce4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,412; copy number 3: 20,491; copy number 4: 21,393; copy number 5: 6,474; copy number 6: 4,315; copy number 7: 650; copy number 8: 192; copy number 9: 39; copy number 10: 104; copy number 11: 134; copy number 12: 79; copy number 13: 94; copy number 14: 169; copy number 15: 93; copy number 17: 89; copy number 19: 68; copy number 22: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A3KU-01A-11D-A227-01): tumor purity 0.78, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 694 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:164,980,035–166,339,090, 31 genes, copy number 10 (within-gene range 3–10): RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2, AL358115.1, MIR3658, AL606495.1, RPS3AP10, RNA5SP64, FAM78B, FAM78B-AS1, AL596087.3, MIR921, AL596087.2.
- chr8:69,922,751–75,352,327, 101 genes, copy number 9–15 (within-gene range 5–15) (broad region; genes not listed).
- chr10:72,367,327–72,626,191, 1 gene, copy number 9 (within-gene range 5–11): MICU1.
- chr10:72,501,746–82,987,179, 225 genes, copy number 10–19 (within-gene range 6–19) (broad region; genes not listed).
- chr10:84,328,586–85,212,800, 8 genes, copy number 9: CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5, AL358787.2, LINC01519, AL358787.1.
- chr11:4,643,420–5,678,434, 87 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr11:11,020,883–12,535,356, 25 genes, copy number 12 (within-gene range 7–12): LINC02752, AC111188.1, AC111188.2, MTND5P21, KC877392.1, GALNT18, CSNK2A3, AC023946.1, AC104031.1, MIR4299, AC131935.2, AC131935.1, AC104383.1, MIR8070, USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA.
- chr11:13,962,723–16,739,591, 27 genes, copy number 12–22 (within-gene range 2–22): SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1.
- chr11:25,140,533–34,147,670, 127 genes, copy number 12–19 (broad region; genes not listed).
- chr18:5,721,812–5,989,369, 4 genes, copy number 9 (within-gene range 7–9): MIR3976HG, MIR3976, TMEM200C, AP001021.1.
- chr18:5,956,101–5,960,785, 1 gene, copy number 9: AP001021.2.
- chr19:27,638,483–30,016,612, 57 genes, copy number 10–11: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
